Somatic mutation profile of tumor specimen C3L-06639-01 (aliquot CPT0358370006) from CPTAC case C3L-06639, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.0 years (25,207 days).
Specimen C3L-06639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 302b53a7-1a6f-4a2a-b12a-f7f9209c8b8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06639-31 (Blood Derived Normal), aliquot CPT0358460005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3642616e-a239-47fb-b5ae-11045daad7f0

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 18, Nonsense Mutation 7, Splice Region 2, Intron 2, RNA 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 64/300 reads (21%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- ZMYND11 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 27/343 reads (8%) | catalogued as rs1060499626; ClinVar: pathogenic; called by muse, mutect2
- ANKRD34C | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 77/473 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs901253440; called by muse, mutect2, varscan2
- BAHCC1 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.127); catalogued as rs782655241; called by muse, mutect2
- BRD8 | c.1117C>T p.R373* (on ENST00000254900 / NM_139199.2; = p.R446* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 28/511 reads (5%) | catalogued as COSV104369206; called by muse, mutect2
- CLOCK | c.665T>C p.L222S | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs1163509746, COSV100011668; called by muse, mutect2
- CTTNBP2NL | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 53/566 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs773905643; called by muse, mutect2
- CYFIP2 | c.3790C>T p.R1264C (on ENST00000616178 / NM_001291722.2; = p.R1239C on NM_014376.4) | Missense Mutation (SNP) | VAF 41/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs371399881; called by muse, mutect2
- DCBLD2 | c.1965C>A p.Y655* | Nonsense Mutation (SNP) | VAF 24/468 reads (5%) | catalogued as rs1363854635; called by muse, mutect2
- DISP3 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 73/469 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs12096312, COSV53833631; called by muse, mutect2, varscan2
- DLGAP3 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs772418605; called by muse, mutect2, varscan2
- DOK5 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 44/798 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs145303661; called by muse, mutect2
- EPHA5 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201120003, COSV56641766; called by muse, mutect2, varscan2
- FANCL | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1012663252, COSV52072640; called by muse, mutect2
- GZMK | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 54/521 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs753500430, COSV50245500; called by muse, mutect2, varscan2
- IGLL5 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs550903741, COSV73251065, COSV73251253; called by muse, mutect2
- KCNA3 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 29/594 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63902535; called by muse, mutect2
- KCTD16 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 33/516 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV72579907; called by muse, mutect2
- KIF5C | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1336945201; called by muse, mutect2
- PCLO | c.15169A>G p.N5057D | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433393; called by muse, mutect2
- PLA2G7 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201567357, COSV51258886; called by muse, mutect2, varscan2
- PLXNA4 | c.4475G>T p.R1492L | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58103431; called by muse, mutect2, varscan2
- PSG1 | c.711G>A p.P237= | Splice Region (SNP) | VAF 41/281 reads (15%) | catalogued as rs4030951, COSV54946847, COSV54957573; called by muse, mutect2, varscan2
- RBMXL3 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 13/351 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.046); catalogued as rs1170570293, COSV57746063; called by muse, mutect2
- RBPJL | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 31/998 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1448551788; called by muse, mutect2
- RYR3 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370528698; called by muse, mutect2
- STAU1 | c.1460C>T p.T487M (on ENST00000371856 / NM_001319135.1; = p.T406M on NM_004602.3) | Missense Mutation (SNP) | VAF 63/729 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs1426079044; called by muse, mutect2
- TBX1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 164/576 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766608075, COSV60353710; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TMEM200A | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771926144; called by muse, mutect2, varscan2
- ARHGAP32 | c.4639C>T p.H1547Y (on ENST00000310343 / NM_001378025.1; = p.H1198Y on NM_014715.4) | Missense Mutation (SNP) | VAF 63/557 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARID1A | c.4284C>A p.Y1428* | Nonsense Mutation (SNP) | VAF 44/407 reads (11%) | called by muse, mutect2, varscan2
- C17orf113 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 75/543 reads (14%) | called by muse, mutect2, varscan2
- DNAH2 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2
- DNAH6 | c.2209C>A p.L737I | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DNASE1 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 42/516 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.114); called by muse, mutect2
- EXT2 | c.522G>A p.M174I (on ENST00000343631; = p.M207I on NM_000401.3) | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXK1 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 91/576 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRY | c.3107T>A p.I1036N | Missense Mutation (SNP) | VAF 226/613 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GAREM2 | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- H2BC10 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.311); called by muse, mutect2
- IFT88 | c.1848del p.Q616Hfs*48 (on ENST00000319980 / NM_001318493.2; = p.Q607Hfs*48 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 36/210 reads (17%) | called by mutect2, pindel, varscan2
- INTS13 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IQANK1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 54/633 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- KBTBD13 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 73/532 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ5 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 72/608 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM4 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAU2 | c.577A>T p.M193L | Missense Mutation (SNP) | VAF 68/341 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- MGAT2 | c.1027_1029del p.D343del | In Frame Del (DEL) | VAF 40/290 reads (14%) | called by pindel, varscan2
- MIA2 | c.177G>T p.L59F | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MYRF | c.2459C>A p.P820H | Missense Mutation (SNP) | VAF 94/688 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NCOA5 | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 69/1142 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.068); called by muse, mutect2
- PDE10A | c.2157G>T p.K719N | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PLEKHH3 | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 111/590 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLXNA2 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PM20D1 | c.976A>T p.R326* | Nonsense Mutation (SNP) | VAF 41/331 reads (12%) | called by muse, mutect2, varscan2
- PRKCI | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIPK1 | c.922T>A p.Y308N | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, varscan2
- RNF214 | c.1152_1156dup p.P386Lfs*18 | Frame Shift Ins (INS) | VAF 32/313 reads (10%) | called by mutect2, pindel
- SLC5A11 | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLCO2A1 | c.627C>T p.S209= | Splice Region (SNP) | VAF 69/361 reads (19%) | called by muse, mutect2, varscan2
- VEGFA | c.241A>G p.M81V (on ENST00000523873 / NM_001171623.1; = p.M261V on NM_003376.6) | Missense Mutation (SNP) | VAF 63/488 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZPR1 | c.1016A>T p.E339V | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AMER2 | c.825C>T p.R275= | Silent (SNP) | VAF 65/659 reads (10%) | catalogued as rs1276861396; called by muse, mutect2
- CDHR1 | c.2478G>A p.P826= | Silent (SNP) | VAF 24/714 reads (3%) | catalogued as COSV60560920; called by muse, mutect2
- CTSG | c.225C>T p.G75= | Silent (SNP) | VAF 41/355 reads (12%) | catalogued as rs143803246, COSV99361379; called by muse, mutect2, varscan2
- FRG2C | c.816T>C p.S272= | Silent (SNP) | VAF 60/898 reads (7%) | called by muse, mutect2
- IFNAR1 | c.180T>C p.T60= | Silent (SNP) | VAF 37/235 reads (16%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.115C>T p.L39= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs186634824; called by muse, mutect2, varscan2
- KIAA1755 | c.1911C>T p.D637= | Silent (SNP) | VAF 52/602 reads (9%) | catalogued as rs112826952; called by muse, mutect2
- LRP1 | c.3873C>T p.V1291= | Silent (SNP) | VAF 62/657 reads (9%) | called by muse, mutect2
- MEN1 | c.1041G>A p.A347= | Silent (SNP) | VAF 74/407 reads (18%) | catalogued as rs878855184, COSV99580014; ClinVar: likely benign; called by muse, mutect2, varscan2
- MSANTD4 | c.687A>G p.E229= | Silent (SNP) | VAF 25/551 reads (5%) | called by muse, mutect2
- MYO15A | c.1260G>A p.S420= | Silent (SNP) | VAF 80/505 reads (16%) | catalogued as rs777228390; called by muse, mutect2, varscan2
- MZF1 | c.1027C>A p.R343= | Silent (SNP) | VAF 65/429 reads (15%) | called by muse, mutect2, varscan2
- NRN1 | c.159G>A p.P53= | Silent (SNP) | VAF 36/334 reads (11%) | catalogued as COSV55206797; called by muse, varscan2
- PHF3 | c.1890T>C p.P630= | Silent (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- PPP4R3C | c.129G>A p.R43= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- TBX2 | c.2016C>T p.R672= | Silent (SNP) | VAF 102/618 reads (17%) | catalogued as rs747949718, COSV53597724; called by muse, mutect2, varscan2
- TTLL10 | c.1737G>A p.S579= | Silent (SNP) | VAF 65/617 reads (11%) | catalogued as rs566976676; called by muse, mutect2, varscan2
- WDR70 | c.1431C>T p.C477= | Silent (SNP) | VAF 23/397 reads (6%) | called by muse, mutect2
- C5orf67 | n.520G>A | RNA (SNP) | VAF 47/445 reads (11%) | catalogued as rs1196544809; called by muse, mutect2, varscan2
- DCHS2 | n.8720A>C | RNA (SNP) | VAF 54/318 reads (17%) | called by muse, mutect2, varscan2
- DLG1 | c.2005-775G>A | Intron (SNP) | VAF 32/266 reads (12%) | catalogued as COSV58392758; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11836G>T | Intron (SNP) | VAF 56/394 reads (14%) | called by mutect2, varscan2
